Somatic mutation profile of tumor specimen TCGA-EE-A2A6-06A (aliquot TCGA-EE-A2A6-06A-11D-A197-08) from TCGA case TCGA-EE-A2A6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.8 years (17,468 days).
Specimen TCGA-EE-A2A6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 496f5dcf-1258-4bf9-a885-e8508a02769f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2A6-10A (Blood Derived Normal), aliquot TCGA-EE-A2A6-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db5f402d-802b-4fc2-b33e-959e4d484306

The open-access MAF lists 358 somatic variants for this specimen: 227 protein-altering or splice-affecting, 122 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 122, Nonsense Mutation 18, Intron 5, Splice Site 3, 3'UTR 2, Frame Shift Del 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL5A1 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs121912933, CM001105, COSV100880190; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ2 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1064795489, COSV60434824; ClinVar: likely pathogenic; called by muse, varscan2
- ABCA13 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780007627, COSV70031519; called by mutect2, varscan2
- AC127029.3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as COSV60110963; called by muse, mutect2, varscan2
- ACAN | c.5747G>A p.S1916N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.774); catalogued as COSV61361990; called by muse, mutect2, varscan2
- ACTL8 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV64861631; called by muse, mutect2
- ADAM2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs773158009, COSV55863118; called by muse, mutect2, varscan2
- ADAM7 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1415288489, COSV51541111; called by muse, mutect2, varscan2
- ADAMTS10 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54355707; called by muse, mutect2, varscan2
- ADAMTS9 | c.2426G>A p.G809E | Missense Mutation (SNP) | VAF 109/492 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55782944; called by muse, mutect2, varscan2
- ADCY2 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV57874435; called by muse, mutect2, varscan2
- ADGRL2 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV54671151, COSV54694588; called by mutect2, varscan2
- AGFG2 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 102/199 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53544863; called by muse, mutect2, varscan2
- ANGPTL2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.489); catalogued as COSV52223799; called by muse, mutect2, varscan2
- ANK2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474105619, COSV52152842; called by muse, mutect2, varscan2
- ANKEF1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as rs1173259468, COSV65692606; called by muse, mutect2, varscan2
- ANKRD36 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV70739470; called by muse, mutect2, varscan2
- ARHGEF17 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55233334; called by muse, mutect2, varscan2
- ARMC9 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV63021393; called by muse, mutect2, varscan2
- ARSH | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.337); catalogued as COSV66963109; called by muse, mutect2, varscan2
- ART3 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV61914373; called by muse, mutect2, varscan2
- ASPHD1 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs757323827, COSV58100198; called by muse, mutect2, varscan2
- ASTN2 | c.3733G>A p.E1245K (on ENST00000313400 / NM_001365069.1; = p.E1194K on NM_014010.5) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV56000282; called by muse, mutect2, varscan2
- BAG4 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV54860632; called by muse, mutect2, varscan2
- BAZ2B | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58602564, COSV58611605; called by muse, mutect2, varscan2
- BIN2 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57205813; called by muse, varscan2
- C6orf15 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV52538529; called by muse, mutect2, varscan2
- CACNA1H | c.6223G>A p.G2075R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as rs541001877, COSV52355276; called by muse, mutect2, varscan2
- CAGE1 | c.1457C>T p.S486F (on ENST00000512086; = p.S350F on NM_205864.3) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV57078067; called by muse, mutect2, varscan2
- CCDC9 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV55721171; called by muse, mutect2, varscan2
- CD1C | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 75/296 reads (25%) | catalogued as rs777559090, COSV63806648; called by muse, mutect2, varscan2
- CDH1 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs761146693, COSV55734099; called by muse, mutect2, varscan2
- CDH9 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50252882; called by muse, mutect2, varscan2
- CDHR4 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV58526271, COSV58526320; called by muse, mutect2, varscan2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CEACAM7 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs1555811263, COSV50073150; called by muse, mutect2, varscan2
- CEACAM8 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs146875157, COSV54990636; called by muse, mutect2, varscan2
- CFAP100 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1199223297, COSV61503341; called by muse, mutect2, varscan2
- CHD9 | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs549002484, COSV54609876; called by muse, mutect2, varscan2
- CLN3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV60491315; called by muse, mutect2, varscan2
- CNTNAP5 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV70489782; called by muse, mutect2
- COL4A5 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.344); catalogued as COSV60357532; called by muse, mutect2, varscan2
- COL6A6 | c.6310G>A p.E2104K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV62027378; called by muse, mutect2, varscan2
- CORO1C | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54596479; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CR1 | c.6074C>T p.P2025L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as rs758680091, COSV65458929; called by muse, mutect2, varscan2
- CSMD2 | c.3611C>T p.S1204F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as rs1433764108, COSV53920008; called by muse, mutect2, varscan2
- CSMD3 | c.8039G>A p.W2680* (on ENST00000297405 / NM_001363185.1; = p.W2576* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV52202946; called by muse, mutect2, varscan2
- CYP3A4 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as CM016156, COSV60501165; called by muse, mutect2, varscan2
- DCTN1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV62620520; called by muse, mutect2, varscan2
- DEFB118 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868083733, COSV53620529; called by muse, mutect2, varscan2
- DENND3 | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52803056; called by muse, mutect2, varscan2
- DGKE | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52350265, COSV99401081; called by mutect2, varscan2
- DNM1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV57851054, COSV57851420, COSV57852347; called by muse, mutect2, varscan2
- DNMBP | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs756073047, COSV60627136; called by muse, mutect2, varscan2
- DOCK2 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as rs267600546, COSV56962911; called by muse, mutect2, varscan2
- DOCK3 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs1470179298, COSV56526849; called by muse, mutect2, varscan2
- DSG4 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.951); catalogued as rs754093240, COSV57392788; called by muse, mutect2, varscan2
- EBNA1BP2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.159); catalogued as COSV52540355; called by muse, mutect2, varscan2
- EDIL3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as rs752603385, COSV56901771; called by mutect2, varscan2
- EDN1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV65080856; called by muse, mutect2, varscan2
- EFCAB13 | c.2240G>A p.R747K | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.11); catalogued as rs749656174, COSV58949297; called by muse, mutect2, varscan2
- EVC2 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100186376; called by muse, mutect2, varscan2
- FAM114A1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV62673216; called by muse, mutect2, varscan2
- FAM120C | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60259753; called by muse, mutect2, varscan2
- FAM209B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs140276541, COSV100990998, COSV64915329; called by muse, mutect2, varscan2
- FAT1 | c.9280C>T p.H3094Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV71674608; called by muse, mutect2, varscan2
- FBN3 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as rs376405342; called by muse, mutect2, varscan2
- FBN3 | c.2510C>T p.T837I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs775757491, COSV54463186; called by muse, mutect2, varscan2
- FGD5 | c.2658G>A p.K886= | Splice Region (SNP) | VAF 21/85 reads (25%) | catalogued as COSV53244623; called by muse, mutect2, varscan2
- FGGY | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58025677; called by muse, mutect2, varscan2
- FLG2 | c.3919G>A p.V1307I | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV66169325; called by muse, mutect2, varscan2
- FOXRED1 | c.1125C>G p.N375K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV55007109; called by muse, varscan2
- FRAS1 | c.8188G>A p.D2730N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53617094; called by muse, mutect2, varscan2
- GALNTL5 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67180276; called by muse, mutect2
- GARNL3 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100150576, COSV59227279; called by muse, mutect2, varscan2
- GBA3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV72438218; called by muse, mutect2, varscan2
- GLIS3 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs997288982, COSV60930215; called by muse, mutect2, varscan2
- GNAL | c.656G>A p.R219K (on ENST00000269162 / NM_001142339.3; = p.R296K on NM_182978.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as COSV52328347, COSV52330759; called by muse, mutect2, varscan2
- GPC4 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV63698201; called by muse, mutect2, varscan2
- GPR152 | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV56885178; called by muse, mutect2, varscan2
- GPRIN2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782485720, COSV65400263, COSV65400709; called by muse, mutect2, varscan2
- HAPLN1 | c.284T>C p.F95S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV57148614; called by muse, mutect2, varscan2
- HAVCR1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 170/639 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59400333; called by muse, mutect2, varscan2
- HBD | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1160528495, COSV53082818; called by muse, mutect2, varscan2
- HCN3 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754322366, COSV61360572; called by muse, mutect2, varscan2
- HECW2 | c.4111C>T p.L1371F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53662036; called by muse, mutect2, varscan2
- HOXA3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV57826876; called by muse, mutect2, varscan2
- HOXB3 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs941219441, COSV57487102; called by muse, mutect2, varscan2
- HSPBAP1 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV60242587, COSV60243490; called by muse, mutect2, varscan2
- ICE1 | c.3959C>T p.P1320L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56826769; called by muse, mutect2, varscan2
- IFNG | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as COSV57491411; called by muse, mutect2, varscan2
- IFTAP | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57557999; called by muse, mutect2, varscan2
- IL9R | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.663); catalogued as rs1447368781, COSV54900301; called by muse, mutect2, varscan2
- ITGB4 | c.4897+1G>A p.X1633_splice | Splice Site (SNP) | VAF 28/69 reads (41%) | catalogued as COSV52327227; called by muse, mutect2, varscan2
- ITIH4 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56574491; called by muse, mutect2, varscan2
- KCNA4 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV60252900; called by muse, mutect2, varscan2
- KIDINS220 | c.4816G>A p.D1606N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.04); catalogued as COSV56754378; called by muse, mutect2, varscan2
- KIF2B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV52131446; called by muse, mutect2, varscan2
- KIR3DL2 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs777900603, COSV54392618; called by muse, mutect2, varscan2
- KLRC4 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV58671960; called by muse, mutect2, varscan2
- KYNU | c.95A>C p.H32P | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51584856; called by muse, mutect2, varscan2
- L1TD1 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.505); catalogued as COSV63133596; called by muse, mutect2, varscan2
- LAMA3 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100557197; called by muse, mutect2, varscan2
- LAMA3 | c.4034T>A p.F1345Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV58070368; called by muse, mutect2, varscan2
- LDHAL6B | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV55688890; called by muse, mutect2, varscan2
- LGR5 | c.1221G>A p.W407* | Nonsense Mutation (SNP) | VAF 142/683 reads (21%) | catalogued as rs777293969, COSV57005710; called by muse, mutect2, varscan2
- LILRA4 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); catalogued as COSV52490667, COSV52492601; called by muse, mutect2, varscan2
- LILRB4 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV54406074; called by muse, mutect2, varscan2
- LRP1B | c.12614G>A p.G4205D | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67230458; called by muse, mutect2, varscan2
- LRTM1 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as COSV55546308; called by muse, mutect2, varscan2
- MAGEL2 | c.3055C>G p.P1019A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.12); catalogued as rs1320725415, COSV100046389, COSV58567532; called by muse, mutect2, varscan2
- MAP4K2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs750045507, COSV53644368; called by muse, mutect2, varscan2
- MBD5 | c.2695C>T p.H899Y | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.133); catalogued as COSV68696401; called by muse, mutect2, varscan2
- ME3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV62772887; called by muse, mutect2, varscan2
- MOSPD3 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.367); catalogued as COSV99774987; called by muse, mutect2, varscan2
- MPPED1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1040473110, COSV61987863; called by muse, mutect2, varscan2
- MTMR10 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58728503; called by muse, mutect2, varscan2
- MTUS2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV70914890; called by muse, mutect2, varscan2
- MUC16 | c.28028C>T p.S9343L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs750811163, COSV101198978, COSV67445063; called by muse, mutect2, varscan2
- MYL1 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.069); catalogued as COSV58975581; called by muse, mutect2, varscan2
- MYO18A | c.4579T>G p.S1527A | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.52); catalogued as COSV62867830; called by muse, mutect2, varscan2
- MYOF | c.5908T>A p.L1970M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV63705343; called by muse, mutect2, varscan2
- MYOM2 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273016042, COSV100036523, COSV100037872; called by muse, mutect2, varscan2
- NLN | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.618); catalogued as COSV101114384; called by muse, mutect2, varscan2
- NOLC1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs770815901, COSV64180282; called by muse, mutect2, varscan2
- NPNT | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV59754441; called by muse, mutect2, varscan2
- NR5A1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1159679614, COSV65295001; called by muse, mutect2, varscan2
- NRXN1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs906827517, COSV101279430, COSV68018753; called by mutect2, varscan2
- OBSCN | c.4655C>T p.A1552V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.522); catalogued as rs1377692449, COSV99481794; called by muse, mutect2, varscan2
- OLFML1 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV55078093; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2V2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60315091, COSV60315740; called by muse, mutect2, varscan2
- OR52E8 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs776313531, COSV66207447; called by muse, mutect2, varscan2
- OR8H3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 74/343 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57908231; called by muse, mutect2, varscan2
- OR8K3 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV57131718; called by muse, mutect2, varscan2
- OR9A2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.665); catalogued as COSV63306693; called by muse, varscan2
- P2RY14 | c.357A>T p.R119S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56381653; called by muse, mutect2, varscan2
- PATL1 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55689963; called by muse, mutect2, varscan2
- PCDH12 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV51521905; called by muse, mutect2, varscan2
- PCDH15 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57281943; called by muse, mutect2, varscan2
- PCDHA3 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs1274408864, COSV63542512; called by mutect2, varscan2
- PCDHA8 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV65327455; called by muse, mutect2, varscan2
- PCDHGA7 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as COSV99542377; called by muse, mutect2, varscan2
- PCDHGA7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.013); catalogued as COSV99542378, COSV99544169; called by muse, mutect2, varscan2
- PCLO | c.10867C>T p.L3623F | Missense Mutation (SNP) | VAF 94/151 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV61639990; called by muse, mutect2, varscan2
- PDE3A | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62973135; called by muse, mutect2, varscan2
- PDHA2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776756344, COSV54778480, COSV54779576; called by muse, mutect2, varscan2
- PDLIM4 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs929254406, COSV53804334; called by muse, mutect2, varscan2
- PHKA1 | c.1246-1G>A p.X416_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV59806962, COSV59811288; called by muse, mutect2
- PHTF1 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63367767; called by muse, mutect2, varscan2
- PIAS1 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV99986935; called by mutect2, varscan2
- PIKFYVE | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as CD118787, COSV100011100; called by muse, mutect2, varscan2
- PIKFYVE | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV100011102; called by muse, mutect2, varscan2
- PLCH1 | c.2998G>A p.A1000T (on ENST00000340059 / NM_001130960.2; = p.A992T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV58186255, COSV58200092; called by muse, mutect2
- PNCK | c.196C>T p.R66C (on ENST00000340888 / NM_001366975.1; = p.R149C on NM_001039582.3) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs139296709, COSV61745767; called by muse, mutect2, varscan2
- PNKP | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV55588434; called by muse, mutect2, varscan2
- PNMA3 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs782050153, COSV64722465; called by muse, mutect2, varscan2
- POLQ | c.4540C>T p.P1514S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV51753732; called by muse, mutect2, varscan2
- PPFIA4 | c.1825A>G p.T609A (on ENST00000447715; = p.T610A on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55316285; called by muse, mutect2, varscan2
- PRPF8 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs779586060, COSV59261689; called by muse, mutect2, varscan2
- PRUNE2 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV65042414; called by muse, mutect2, varscan2
- PSG9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs866050640, COSV52483314; called by muse, mutect2, varscan2
- PSMD4 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV64393234; called by muse, mutect2, varscan2
- QSOX1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV62580645; called by muse, mutect2, varscan2
- RAB11FIP4 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV57928970; called by muse, mutect2, varscan2
- RALGAPA1 | c.4388C>A p.P1463H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99355320; called by muse, mutect2, varscan2
- RALGAPA1 | c.4387C>T p.P1463S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV99355434; called by muse, mutect2, varscan2
- RASGRF2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54131434, COSV54140828; called by mutect2, varscan2
- RELN | c.5419G>A p.D1807N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); catalogued as rs558284872, COSV59007649; called by muse, mutect2, varscan2
- RIBC1 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV51448211; called by muse, mutect2, varscan2
- RNF20 | c.2382+1G>A p.X794_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV66661308; called by muse, mutect2, varscan2
- RPTN | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 119/584 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV60167533; called by muse, mutect2, varscan2
- RTP1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56618487; called by muse, mutect2, varscan2
- RYR2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV63689925; called by muse, mutect2, varscan2
- SCGN | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760647578, COSV58546220; called by muse, mutect2, varscan2
- SCN7A | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.197); catalogued as COSV101313241, COSV69269643; called by muse, mutect2, varscan2
- SEC14L3 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53178124; called by muse, mutect2, varscan2
- SELPLG | c.1229T>C p.F410S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947535; called by muse, mutect2, varscan2
- SELPLG | c.1228T>C p.F410L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99947536; called by muse, mutect2, varscan2
- SH3D19 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV58790521, COSV58791065; called by muse, mutect2, varscan2
- SLC17A6 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54137232; called by muse, mutect2, varscan2
- SLC1A2 | c.303A>C p.L101F | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53522198; called by muse, mutect2, varscan2
- SLC1A7 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV65195354; called by muse, mutect2, varscan2
- SLC27A2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51059628; called by muse, mutect2, varscan2
- SLC35E3 | c.766T>C p.F256L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV60117969; called by muse, mutect2, varscan2
- SLC6A13 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as rs781142259, COSV58255103; called by muse, mutect2, varscan2
- SLC8B1 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.066); catalogued as COSV52528542; called by muse, mutect2, varscan2
- SLC9A3 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1337944503, COSV53801886; called by muse, mutect2, varscan2
- SMARCA4 | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs866735560, COSV60796903; called by muse, mutect2, varscan2
- SNAPC4 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV53730481; called by muse, varscan2
- SP100 | c.239A>T p.D80V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50982338; called by muse, mutect2
- SPATA6L | c.641G>A p.G214E (on ENST00000461761 / NM_001353484.2; = p.G156E on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755997192, COSV56305814; called by muse, mutect2, varscan2
- SPINK5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as rs1414075876, COSV56255889; called by muse, mutect2, varscan2
- SPRR2D | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 144/371 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs756758146, COSV100835985, COSV64209038; called by muse, mutect2, varscan2
- STAB1 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308140493, COSV58737662; called by muse, mutect2, varscan2
- STAP1 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs267600208, COSV55327318; called by muse, mutect2, varscan2
- TARS2 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64695707; called by muse, mutect2, varscan2
- TBP | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.039); catalogued as COSV57832187; called by muse, varscan2
- TEX11 | c.211G>A p.E71K (on ENST00000344304; = p.E56K on NM_031276.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1392057829, COSV60232178; called by muse, mutect2, varscan2
- TKT | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV56245687; called by muse, mutect2, varscan2
- TLL1 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV50290317; called by muse, mutect2, varscan2
- TMC2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461476053, COSV62652818; called by muse, mutect2, varscan2
- TMEM131L | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as rs191244971, COSV53643436; called by muse, mutect2, varscan2
- TNR | c.2408G>A p.R803K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV54890120; called by muse, varscan2
- TRIM42 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.272); catalogued as COSV53883719; called by muse, mutect2, varscan2
- TRIM49 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100316156; called by muse, mutect2, varscan2
- TRIML2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV58715990; called by muse, mutect2, varscan2
- TTLL13P | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as COSV60038254; called by muse, mutect2, varscan2
- UBLCP1 | c.918A>T p.K306N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV57143514; called by muse, mutect2, varscan2
- UBR4 | c.9544C>T p.P3182S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.979); catalogued as COSV64391318; called by muse, mutect2, varscan2
- USH2A | c.5704G>A p.G1902R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56381462; called by muse, mutect2, varscan2
- USP2 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 107/433 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52729919; called by muse, mutect2, varscan2
- USP48 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | catalogued as COSV57610913; called by muse, mutect2, varscan2
- VAV1 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV58385249; called by muse, mutect2, varscan2
- VEGFC | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs745519188, COSV54594404; called by muse, varscan2
- VPS13D | c.5182C>T p.H1728Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV50645169; called by muse, mutect2, varscan2
- WDR90 | c.4880C>T p.T1627M | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs753403076, COSV53469201; called by muse, mutect2, varscan2
- ZNF160 | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as COSV61999931; called by muse, mutect2, varscan2
- ZNF431 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV60673480; called by muse, mutect2, varscan2
- ZNF711 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as rs1421762656, COSV52155452; called by muse, mutect2, varscan2
- ZNF790 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as rs766514175, COSV63212599; called by muse, mutect2, varscan2
- IGLV4-69 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KIR3DL2 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- KLHL23 | c.462_474del p.K156Efs*42 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- ABCA13 | c.1029C>T p.V343= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV70031546; called by muse, mutect2, varscan2
- ABHD17A | c.264C>T p.V88= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV51750833; called by muse, mutect2, varscan2
- ADAM29 | c.1521G>A p.R507= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs267600092, COSV63661987, COSV63664066; called by muse, mutect2, varscan2
- AKT2 | c.546C>T p.I182= | Silent (SNP) | VAF 69/250 reads (28%) | catalogued as COSV60908705; called by muse, mutect2, varscan2
- ALDH3B2 | c.654C>T p.G218= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV62428530; called by muse, mutect2, varscan2
- ALS2CL | c.1146G>A p.V382= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV59671854; called by muse, mutect2, varscan2
- AMBRA1 | c.558G>A p.V186= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV54055551; called by muse, mutect2, varscan2
- APLNR | c.648C>T p.I216= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV57242947; called by muse, mutect2, varscan2
- ARHGEF15 | c.879C>T p.F293= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs764749566, COSV62725339; ClinVar: likely benign; called by mutect2, varscan2
- C1QTNF9 | c.981C>T p.F327= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV59657359; called by muse, mutect2, varscan2
- C2orf16 | c.1971G>A p.V657= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1394441793, COSV62676253; called by muse, mutect2, varscan2
- CACNA1D | c.3060C>T p.I1020= (on ENST00000350061 / NM_001128840.3; = p.I1040= on NM_000720.4) | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs768453719, COSV55450060; called by muse, mutect2, varscan2
- CD22 | c.570G>A p.S190= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs761690391, COSV50054291; called by muse, mutect2, varscan2
- CD33 | c.609C>T p.P203= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV51802231; called by muse, mutect2, varscan2
- CEACAM5 | c.471G>A p.V157= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs868989731, COSV55752581; called by muse, mutect2, varscan2
- CLCN2 | c.675C>T p.L225= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs759950295, COSV55601777; called by muse, mutect2, varscan2
- CLCNKA | c.1767C>T p.I589= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV58891998; called by muse, mutect2, varscan2
- CLPB | c.1863C>T p.S621= | Silent (SNP) | VAF 93/362 reads (26%) | catalogued as COSV53630412; called by muse, mutect2, varscan2
- CNTNAP2 | c.1632C>T p.F544= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as rs778731812, COSV62144222; ClinVar: likely benign; called by muse, mutect2, varscan2
- COLEC12 | c.667C>T p.L223= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV68371130; called by muse, mutect2, varscan2
- CPN2 | c.423C>T p.F141= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV60470700; called by muse, mutect2, varscan2
- CSF3 | c.531C>T p.F177= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV56641096; called by muse, mutect2, varscan2
- DHX8 | c.3333C>T p.F1111= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV52250898, COSV52253922; called by muse, mutect2, varscan2
- DNAH5 | c.10659G>A p.R3553= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV54230826; called by muse, mutect2, varscan2
- DNAH5 | c.6408G>A p.T2136= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs765298305, COSV54230840; called by muse, mutect2, varscan2
- DOCK6 | c.3976C>T p.L1326= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV53910931, COSV53916033; called by muse, mutect2, varscan2
- DPP6 | c.336C>T p.T112= (on ENST00000377770 / NM_001364500.2; = p.T50= on NM_001936.5) | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs374577318, COSV100125228; called by muse, mutect2, varscan2
- EDAR | c.1113G>A p.V371= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV51503740; called by muse, mutect2, varscan2
- ELL | c.1644G>A p.R548= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99443492; called by muse, varscan2
- EP300 | c.1897C>T p.L633= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV54334358; called by muse, mutect2, varscan2
- ESYT1 | c.1713C>T p.I571= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs896120058, COSV57273883; called by muse, mutect2, varscan2
- EVC2 | c.2379G>A p.G793= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs984357172, COSV100186378; called by muse, mutect2, varscan2
- F2 | c.1524G>A p.K508= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV61316037; called by muse, mutect2, varscan2
- FLG2 | c.3000C>T p.G1000= | Silent (SNP) | VAF 177/394 reads (45%) | catalogued as COSV66169328; called by muse, mutect2, varscan2
- GFI1 | c.303G>A p.S101= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs766935424, COSV54042943; called by muse, mutect2, varscan2
- GLB1 | c.1947C>T p.T649= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs1289878163, COSV56564697; called by muse, mutect2, varscan2
- GNA14 | c.399A>G p.Q133= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV59024644; called by muse, mutect2, varscan2
- GNPDA1 | c.471C>T p.T157= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs139642867; called by muse, mutect2, varscan2
- GRID1 | c.90C>T p.F30= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV60032872; called by muse, mutect2, varscan2
- GRK7 | c.258C>T p.F86= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV53821540; called by muse, mutect2, varscan2
- HP | c.834G>A p.V278= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV63326048; called by muse, mutect2, varscan2
- HRH1 | c.1218C>T p.H406= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV67955549; called by muse, mutect2, varscan2
- HS3ST4 | c.1176G>A p.K392= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100501580, COSV58806585; called by muse, mutect2, varscan2
- ITGB4 | c.3060G>A p.G1020= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52323574; called by muse, mutect2
- ITPR1 | c.7935C>T p.I2645= (on ENST00000354582; = p.I2590= on NM_002222.7) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs371988852; ClinVar: conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- ITPRID2 | c.3561T>A p.V1187= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV57472747; called by muse, mutect2, varscan2
- ITPRIP | c.633C>T p.F211= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs905114549, COSV53390514; called by muse, mutect2, varscan2
- KCNF1 | c.1167C>T p.I389= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV54463846; called by muse, mutect2, varscan2
- KIAA1217 | c.4788G>A p.G1596= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV56817804; called by muse, mutect2, varscan2
- KRT37 | c.1140G>A p.L380= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV56658419; called by muse, mutect2, varscan2
- LPAR1 | c.474G>A p.R158= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1053720841, COSV62689270; called by muse, mutect2, varscan2
- LRRC6 | c.996C>T p.I332= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV51542997; called by muse, mutect2, varscan2
- LTBP1 | c.4155A>G p.E1385= (on ENST00000404816 / NM_206943.4; = p.E1059= on NM_000627.4) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV55380357; called by muse, mutect2, varscan2
- LTF | c.1191G>A p.E397= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV51608809; called by muse, mutect2, varscan2
- MC3R | c.912G>A p.L304= | Silent (SNP) | VAF 101/231 reads (44%) | catalogued as COSV54763944; called by muse, mutect2, varscan2
- MOSPD3 | c.33G>A p.L11= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99774986; called by muse, mutect2, varscan2
- MPP6 | c.72C>T p.F24= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV56038507; called by muse, mutect2
- MRGPRX1 | c.108C>T p.I36= | Silent (SNP) | VAF 37/252 reads (15%) | catalogued as COSV57107605, COSV57107683; called by muse, varscan2
- MROH1 | c.801C>T p.L267= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1426100390, COSV58190149; called by mutect2, varscan2
- MSN | c.1608C>T p.S536= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV64304331; called by muse, mutect2, varscan2
- MUC16 | c.24480C>T p.S8160= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV67472014; called by muse, mutect2, varscan2
- MXRA5 | c.7947C>T p.I2649= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV54238156; called by muse, mutect2, varscan2
- MYH7 | c.2538G>A p.E846= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV62520095; called by muse, mutect2, varscan2
- MYMK | c.81G>A p.K27= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs765073753, COSV60600976; called by muse, mutect2, varscan2
- MYOM2 | c.3087G>A p.K1029= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs199799785, COSV100037943, COSV50731434; called by muse, mutect2, varscan2
- NLRP13 | c.2085C>T p.I695= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs769035639, COSV61622240; called by muse, mutect2, varscan2
- NOLC1 | c.1869C>T p.S623= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs746943493, COSV100893716; called by muse, mutect2, varscan2
- NOX5 | c.2103G>A p.E701= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV52989908; called by muse, mutect2, varscan2
- NPAP1 | c.135C>T p.R45= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs762822123, COSV61507786; called by muse, mutect2, varscan2
- NUP188 | c.3621C>T p.F1207= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV65362836; called by muse, mutect2, varscan2
- OBSCN | c.4656C>T p.A1552= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1241480395, COSV99481798; called by muse, mutect2, varscan2
- OR2A12 | c.612C>T p.F204= | Silent (SNP) | VAF 49/257 reads (19%) | catalogued as rs749780355, COSV68821579; called by muse, mutect2, varscan2
- OR8K1 | c.240C>T p.S80= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs771373964, COSV54402886; called by muse, mutect2, varscan2
- PAPPA2 | c.2568C>T p.T856= | Silent (SNP) | VAF 40/225 reads (18%) | catalogued as COSV62779636, COSV62780953; called by muse, mutect2, varscan2
- PCDH8 | c.2124C>T p.F708= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58812924; called by muse, mutect2, varscan2
- PCDHAC2 | c.363G>A p.L121= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV53853243; called by muse, mutect2, varscan2
- PCLO | c.9348G>A p.R3116= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs557802584, COSV100435744, COSV61639998; called by muse, mutect2, varscan2
- PCM1 | c.4944A>G p.Q1648= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs756849356, COSV59587087; called by muse, mutect2, varscan2
- PCSK5 | c.2568C>T p.C856= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs138803714; called by muse, mutect2, varscan2
- PDILT | c.528C>T p.I176= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs186692475, COSV56701147; called by muse, mutect2, varscan2
- PGLYRP3 | c.612C>T p.V204= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs1204394841, COSV51950669; called by muse, mutect2, varscan2
- PKD2L1 | c.750G>A p.Q250= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58396446; called by muse, mutect2, varscan2
- PKHD1L1 | c.5094C>T p.F1698= | Silent (SNP) | VAF 60/190 reads (32%) | catalogued as COSV65744776; called by muse, mutect2, varscan2
- PLEKHM1 | c.501C>T p.F167= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV69598710; called by muse, mutect2, varscan2
- PNCK | c.195C>T p.L65= (on ENST00000340888 / NM_001366975.1; = p.L148= on NM_001039582.3) | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100562396; called by muse, mutect2, varscan2
- PPIP5K2 | c.3447C>T p.S1149= (on ENST00000358359 / NM_001276277.3; = p.S1128= on NM_015216.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs903599195, COSV58606221; called by muse, mutect2, varscan2
- PPP1R1C | c.117G>A p.V39= | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as COSV54716451; called by muse, mutect2, varscan2
- PREX2 | c.465G>A p.R155= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs746159820, COSV55775921; called by muse, mutect2, varscan2
- PTPRF | c.3000C>T p.S1000= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100741053; called by muse, mutect2, varscan2
- RBM27 | c.468C>T p.Y156= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs533283158, COSV54590564; called by muse, mutect2, varscan2
- RETNLB | c.105C>T p.I35= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV55465732; called by muse, mutect2, varscan2
- ROR2 | c.1797C>T p.I599= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs754344192, COSV65219865; called by muse, mutect2, varscan2
- RP1 | c.144C>T p.F48= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV55110759; called by muse, mutect2, varscan2
- RPS20 | c.240C>T p.F80= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV50536574; called by muse, mutect2, varscan2
- SCG3 | c.1143A>G p.G381= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV55021605; called by muse, mutect2, varscan2
- SELENOV | c.951C>T p.V317= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as COSV59064037; called by muse, mutect2, varscan2
- SLC6A19 | c.1155C>T p.I385= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV58671857; called by muse, mutect2, varscan2
- SLIT2 | c.2535C>T p.F845= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99885564; called by muse, mutect2, varscan2
- SNAI2 | c.747C>T p.T249= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV50079301; called by muse, mutect2, varscan2
- SPATA20 | c.2166C>T p.V722= (on ENST00000356488 / NM_001258372.1; = p.V738= on NM_022827.4) | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as rs1234790335, COSV50067045; called by muse, mutect2, varscan2
- STARD8 | c.1122C>T p.A374= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52927680; called by muse, mutect2, varscan2
- STC1 | c.324C>T p.F108= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs267601859, COSV51687863; called by muse, mutect2, varscan2
- TFDP1 | c.360C>T p.S120= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1432356315, COSV64740740; called by muse, mutect2, varscan2
- TGM4 | c.180G>A p.L60= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV56094292; called by muse, mutect2, varscan2
- THBS1 | c.201C>T p.I67= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs747664282, COSV52949806; called by mutect2, varscan2
- TLE4 | c.570C>T p.H190= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV54633350; called by muse, mutect2, varscan2
- TLR8 | c.2349C>T p.F783= (on ENST00000218032 / NM_138636.5; = p.F801= on NM_016610.4) | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as rs1318685686, COSV54318528; called by muse, mutect2, varscan2
- TPO | c.867C>T p.F289= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs757602334, COSV61103361; called by muse, mutect2, varscan2
- TRIO | c.6474C>T p.I2158= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs754779359, COSV60085438; called by mutect2, varscan2
- TRPC6 | c.786G>A p.Q262= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV60255868; called by muse, mutect2, varscan2
- TSHZ2 | c.439C>T p.L147= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV61589279; called by muse, mutect2, varscan2
- TTC27 | c.1458A>G p.E486= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV58653085; called by muse, mutect2, varscan2
- TTN | c.23571G>A p.V7857= (on ENST00000591111; = p.V6930= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV60114448; called by muse, mutect2, varscan2
- TUBA3C | c.1002C>T p.T334= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV68028320; called by muse, mutect2, varscan2
- UNC13C | c.4500C>T p.N1500= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52882263, COSV99523304; called by muse, mutect2
- VTCN1 | c.249C>T p.F83= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV60223809; called by muse, mutect2, varscan2
- ZNF460 | c.1233C>T p.F411= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV64415791; called by muse, mutect2, varscan2
- ZNF507 | c.1689C>T p.T563= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV61331774; called by muse, mutect2, varscan2
- ZNF536 | c.2898G>A p.R966= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs771734169, COSV62824499; called by muse, mutect2, varscan2
- ZNF71 | c.1125C>T p.I375= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV60148415; called by muse, mutect2, varscan2
- ZNF831 | c.651G>A p.G217= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs762477318, COSV64041184; called by muse, mutect2, varscan2
- ZNRF3 | c.1767C>T p.S589= (on ENST00000544604 / NM_001206998.2; = p.S489= on NM_032173.3) | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV60435047; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849021 G>A | 5'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- CSH1 | c.457-75G>A | Intron (SNP) | VAF 33/141 reads (23%) | catalogued as COSV100298399; called by muse, mutect2, varscan2
- GLYATL1 | c.-85C>T | 5'UTR (SNP) | VAF 10/42 reads (24%) | catalogued as rs766734539, COSV55609263; called by muse, mutect2, varscan2
- LY9 | c.454+1830G>T | Intron (SNP) | VAF 40/92 reads (43%) | catalogued as COSV99627039; called by muse, mutect2, varscan2
- MAGEA10 | c.*2G>A | 3'UTR (SNP) | VAF 39/75 reads (52%) | catalogued as rs766758155, COSV54882784, COSV99726811; called by muse, mutect2, varscan2
- MGAM | c.4618+150C>T | Intron (SNP) | VAF 47/91 reads (52%) | catalogued as COSV101527379; called by muse, mutect2, varscan2
- PDE4B | c.281+74199C>T | Intron (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100304280; called by muse, mutect2, varscan2
- PRSS37 | c.*1G>A | 3'UTR (SNP) | VAF 62/122 reads (51%) | catalogued as COSV100633886; called by muse, varscan2
- TTN | c.10361-5351C>T | Intron (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100621105; called by muse, mutect2, varscan2
